Somatic mutation profile of tumor specimen TCGA-C5-A2LY-01A (aliquot TCGA-C5-A2LY-01A-31D-A18J-09) from TCGA case TCGA-C5-A2LY, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 30.2 years (11,018 days).
Specimen TCGA-C5-A2LY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddc3c5e3-35dc-4172-85b3-668cb0d6ca34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A2LY-10A (Blood Derived Normal), aliquot TCGA-C5-A2LY-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a60739b-02c5-43f9-88f7-2aee053186b4

The open-access MAF lists 97 somatic variants for this specimen: 68 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 26, Nonsense Mutation 7, RNA 2, Splice Region 1, Intron 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC023055.1 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60242787; called by muse, mutect2, varscan2
- ATP13A5 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV60868651, COSV60876951; called by muse, mutect2, varscan2
- B3GNT5 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV58475736; called by muse, mutect2, varscan2
- CACNA1H | c.6677C>T p.T2226M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.086); catalogued as rs751787751, COSV52352653; called by muse, mutect2, varscan2
- CCDC6 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs983534852, COSV54057008; called by muse, mutect2, varscan2
- CSPP1 | c.1579G>A p.A527T (on ENST00000676605; = p.A486T on NM_024790.6) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs374214705; called by muse, mutect2, varscan2
- CUEDC1 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as rs762874769, COSV100804808; called by muse, mutect2, varscan2
- CYP11B1 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV52827474; called by muse, mutect2, varscan2
- DLG2 | c.2391A>C p.K797N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54682703; called by muse, mutect2, varscan2
- FAM47C | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as COSV100792643; called by muse, mutect2
- FNBP4 | c.2317C>A p.Q773K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.444); catalogued as COSV99771699; called by muse, mutect2
- FPGT | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV63834630; called by muse, mutect2, varscan2
- GMPS | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1421362213; called by muse, mutect2, varscan2
- GPR34 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.108); catalogued as rs61734983, COSV59364499; called by muse, mutect2, varscan2
- H2AX | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99598061, COSV99598297; called by muse, mutect2, varscan2
- H2BC3 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1406871808; called by muse, mutect2, varscan2
- HERC2 | c.6269C>T p.A2090V | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs753308541, COSV55345773; called by muse, mutect2, varscan2
- IL3RA | c.879C>G p.C293W | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs367747585, COSV100452240; called by muse, mutect2, varscan2
- KIF3B | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV100996390; called by muse, mutect2, varscan2
- KRBOX4 | c.337G>T p.E113* (on ENST00000344302 / NM_001129898.2; = p.E108* on NM_017776.2) | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99994339; called by muse, mutect2, varscan2
- MCF2L | c.2365G>A p.E789K (on ENST00000375608; = p.E757K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs1441026981, COSV99995807; called by muse, mutect2
- MDM2 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs1330733959; called by muse, varscan2
- MKI67 | c.8775_8776del p.Q2926Nfs*6 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs1173089014; called by pindel, varscan2
- NPHS1 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62290240; called by muse, mutect2, varscan2
- PCDHB7 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50756530, COSV50784392; called by muse, mutect2, varscan2
- PIK3CG | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs765226775; called by muse, mutect2, varscan2
- RBM10 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1556771063; called by muse, mutect2, varscan2
- RHPN1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs150183295; called by muse, mutect2, varscan2
- SYT3 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58897862; called by muse, mutect2, varscan2
- TRIO | c.2214C>T p.L738= | Splice Region (SNP) | VAF 30/80 reads (38%) | catalogued as COSV60088223; called by muse, mutect2, varscan2
- UHRF1BP1L | c.4178G>A p.R1393H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs61743540, COSV54434395; called by muse, mutect2, varscan2
- UPF1 | c.1201G>C p.E401Q (on ENST00000599848 / NM_001297549.2; = p.E390Q on NM_002911.4) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV53199015, COSV53200443, COSV99439268; called by muse, mutect2, varscan2
- WDR93 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as rs375352738; called by muse, mutect2, varscan2
- ZNF227 | c.2373G>C p.Q791H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs776669297, COSV57312882; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.2758G>T p.E920* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- ARF6 | c.390G>C p.M130I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ARHGEF6 | c.1331T>C p.I444T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CNOT3 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CWH43 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EP300 | c.2200C>T p.Q734* | Nonsense Mutation (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- FBN1 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GBX2 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIPK3 | c.1603C>G p.H535D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- HNRNPM | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- IER5 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IHH | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- KRT80 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGI1 | c.503+1G>T p.X168_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- MGAT4C | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- MOCS3 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MON2 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ODF2 | c.1618G>A p.E540K (on ENST00000434106 / NM_153433.2; = p.E516K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- PDZD2 | c.8395G>C p.E2799Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNPLA7 | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PPFIA3 | c.2263C>T p.H755Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- RNF31 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | called by muse, varscan2
- RTN3 | c.1115C>T p.S372L (on ENST00000377819 / NM_001265589.2; = p.S353L on NM_201428.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by mutect2, varscan2
- SF3A3 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SLC12A4 | c.1869G>C p.M623I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- SLC9A7 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SYN3 | c.692T>C p.F231S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- TFAM | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by mutect2, varscan2
- WBP2 | c.240_241del p.C80* | Nonsense Mutation (DEL) | VAF 22/104 reads (21%) | called by pindel, varscan2
- WNK3 | c.3900G>A p.M1300I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP69B | c.1237C>G p.H413D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF318 | c.3904G>C p.E1302Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZNF474 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ACE | c.3681G>A p.T1227= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs751171602, COSV52011054; called by muse, mutect2, varscan2
- ARSF | c.1365C>T p.A455= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs144086355, COSV63839404; called by muse, mutect2, varscan2
- CAPN15 | c.2073C>G p.L691= | Silent (SNP) | VAF 40/128 reads (31%) | called by muse, mutect2, varscan2
- CD7 | c.132C>T p.V44= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1203333943; called by muse, mutect2, varscan2
- COPA | c.3396G>A p.G1132= | Silent (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- DCLK2 | c.873G>A p.L291= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99652239; called by muse, mutect2, varscan2
- EDEM2 | c.1440C>T p.I480= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs747948905, COSV63259624; called by muse, mutect2, varscan2
- ELMO3 | c.54C>T p.L18= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs1394552393, COSV62606266; called by muse, mutect2, varscan2
- FERD3L | c.354C>T p.N118= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV51764456; called by muse, mutect2, varscan2
- GCDH | c.576G>A p.E192= | Silent (SNP) | VAF 123/197 reads (62%) | called by muse, mutect2, varscan2
- GPR6 | c.258C>A p.I86= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as COSV51572797; called by muse, mutect2, varscan2
- H2BC18 | c.222C>T p.I74= | Silent (SNP) | VAF 55/256 reads (21%) | catalogued as rs782575950, COSV100516145, COSV58944587; called by muse, mutect2, varscan2
- HAGH | c.237G>A p.V79= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs1430527189; called by muse, mutect2, varscan2
- KIF1C | c.2100G>A p.P700= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs763581921; called by muse, mutect2, varscan2
- MFSD11 | c.897G>C p.L299= | Silent (SNP) | VAF 5/103 reads (5%) | catalogued as COSV100333943; called by muse, mutect2
- MUC16 | c.23553C>G p.V7851= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs775094802; called by muse, mutect2, varscan2
- OR2T10 | c.750C>T p.L250= | Silent (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- PKN1 | c.2472C>T p.F824= | Silent (SNP) | VAF 285/368 reads (77%) | catalogued as rs758955037, COSV52874419; called by muse, mutect2, varscan2
- RPP40 | c.66C>T p.F22= | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- RTL6 | c.522G>A p.R174= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs771332168; called by muse, mutect2, varscan2
- SGSM2 | c.2985C>T p.L995= (on ENST00000426855 / NM_001098509.2; = p.L1040= on NM_014853.3) | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs773330310; called by muse, mutect2, varscan2
- STAT5A | c.1146G>A p.L382= | Silent (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- SYNGAP1 | c.2718C>G p.L906= | Silent (SNP) | VAF 67/127 reads (53%) | catalogued as COSV53381194; called by muse, mutect2, varscan2
- TRABD | c.441G>C p.L147= | Silent (SNP) | VAF 4/97 reads (4%) | called by muse, mutect2
- WDR46 | c.1779G>A p.A593= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs2475, COSV101005597; called by muse, mutect2, varscan2
- ZNF765 | c.1347C>T p.F449= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV101125546; called by muse, mutect2, varscan2
- DCHS2 | n.5191T>C | RNA (SNP) | VAF 5/15 reads (33%) | catalogued as rs751108900; called by muse, mutect2, varscan2
- FAM74A3 | n.186C>G | RNA (SNP) | VAF 44/235 reads (19%) | called by muse, mutect2, varscan2
- PRKG1 | c.935+176G>C | Intron (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
